Somatic mutation profile of tumor specimen TCGA-BF-A1PZ-01A (aliquot TCGA-BF-A1PZ-01A-11D-A19A-08) from TCGA case TCGA-BF-A1PZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.8 years (26,240 days).
Specimen TCGA-BF-A1PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e7ae545-8168-46e3-8b7f-811ad4be554b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A1PZ-10A (Blood Derived Normal), aliquot TCGA-BF-A1PZ-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4598efaf-e57f-42a6-bc40-5559c80387e6

The open-access MAF lists 285 somatic variants for this specimen: 190 protein-altering or splice-affecting, 92 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 92, Nonsense Mutation 15, Splice Site 5, RNA 3, Splice Region 2, Translation Start Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6428-2A>G p.X2143_splice (on ENST00000358273 / NM_001042492.3; = p.X2122_splice on NM_000267.3) | Splice Site (SNP) | VAF 22/39 reads (56%) | catalogued as rs1060500312, CS066641, CS165122, COSV62218252; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 104/127 reads (82%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TCF20 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59491013; called by muse, mutect2, varscan2
- A1CF | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV51006735; called by muse, mutect2, varscan2
- AADACL2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV62932244; called by muse, mutect2, varscan2
- ABCG1 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59209699; called by muse, varscan2
- ACOX3 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV62713542; called by mutect2, varscan2
- ACOX3 | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV100711961; called by muse, mutect2, varscan2
- ACR | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as COSV53361847; called by muse, mutect2, varscan2
- ACVR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751000395, COSV55116085; called by muse, mutect2, varscan2
- ADAMTS6 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV66863947; called by muse, mutect2, varscan2
- ADARB2 | c.1444C>T p.H482Y | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67234790; called by muse, mutect2, varscan2
- ADCY8 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1433282186, COSV53933309, COSV99654063; called by mutect2, varscan2
- AHDC1 | c.4222T>A p.F1408I | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV55941971; called by muse, mutect2, varscan2
- ANK1 | c.2798G>A p.G933D | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV55875843; called by muse, mutect2, varscan2
- ANKRD30A | c.647G>A p.G216E (on ENST00000611781; = p.G160E on NM_052997.2) | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100654523, COSV64619253; called by muse, mutect2, varscan2
- ARSG | c.627T>G p.I209M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777274147, COSV71593919; called by muse, mutect2, varscan2
- ATP13A4 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV55074416; called by muse, mutect2, varscan2
- ATP4A | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV52871363; called by muse, mutect2
- BAP1 | c.1928T>C p.I643T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs376519545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.10454C>T p.S3485F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56526135; called by muse, mutect2, varscan2
- C1orf194 | c.132G>A p.W44* (on ENST00000369948 / NM_001245025.3; = p.W32* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 117/124 reads (94%) | catalogued as COSV100885165; called by muse, mutect2, varscan2
- C1orf194 | c.131G>A p.W44* (on ENST00000369948 / NM_001245025.3; = p.W32* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 121/128 reads (95%) | catalogued as COSV64050018; called by muse, mutect2, varscan2
- C2CD6 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53795050; called by muse, mutect2, varscan2
- CACNA2D1 | c.2183G>A p.G728E (on ENST00000356253 / NM_001366867.1; = p.G716E on NM_000722.4) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62383805; called by muse, mutect2, varscan2
- CAVIN2 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV58425651; called by muse, varscan2
- CHD7 | c.6425C>T p.S2142F | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV71107554; called by muse, mutect2, varscan2
- COL5A3 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs936145198, COSV99318790, COSV99319006; called by muse, mutect2, varscan2
- COL5A3 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99318219; called by muse, mutect2, varscan2
- CREB5 | c.1100G>A p.R367Q (on ENST00000357727 / NM_182898.4; = p.R360Q on NM_004904.3) | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV63227742; called by mutect2, varscan2
- CRHBP | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 150/176 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.425); catalogued as COSV57188272, COSV57189780; called by muse, varscan2
- CYP4B1 | c.321G>A p.G107= | Splice Region (SNP) | VAF 16/16 reads (100%) | catalogued as COSV54725758; called by muse, mutect2, varscan2
- DDX3X | c.1969G>T p.D657Y (on ENST00000399959; = p.D658Y on NM_001356.5) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67864405; called by mutect2, varscan2
- DHX36 | c.658A>C p.I220L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as COSV57676664; called by muse, mutect2, varscan2
- DHX38 | c.3256-1G>A p.X1086_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99194333; called by muse, mutect2, varscan2
- DISP2 | c.2578G>A p.G860S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.742); catalogued as rs779995639, COSV51145290, COSV99140911; called by mutect2, varscan2
- DISP2 | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.73); catalogued as COSV99140066; called by muse, mutect2
- DLGAP3 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.526); catalogued as COSV52396975; called by muse, mutect2, varscan2
- DNAH2 | c.5500G>A p.D1834N | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66725662; called by muse, mutect2, varscan2
- DNAH9 | c.12676G>A p.E4226K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV52372756; called by muse, mutect2, varscan2
- DOCK2 | c.4598G>A p.G1533E | Missense Mutation (SNP) | VAF 80/90 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56951238; called by muse, mutect2, varscan2
- DOP1B | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67695700; called by muse, mutect2, varscan2
- DSCAM | c.2651-1G>T p.X884_splice | Splice Site (SNP) | VAF 16/18 reads (89%) | catalogued as COSV68034632; called by mutect2, varscan2
- DSE | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59066952; called by muse, mutect2, varscan2
- DYRK1A | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV58709434; called by mutect2, varscan2
- EHHADH | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV51633044; called by muse, mutect2, varscan2
- ENOX2 | c.715C>T p.P239S (on ENST00000338144 / NM_001382520.1; = p.P210S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV57657269; called by muse, mutect2, varscan2
- ENPP1 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs200239821, COSV62935669; called by muse, varscan2
- EXOSC5 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs772326120, COSV54199449; called by muse, mutect2, varscan2
- FAM135B | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs867284054, COSV52749527; called by muse, mutect2, varscan2
- FAM162A | c.48G>C p.R16S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51659488; called by muse, mutect2, varscan2
- FBXL5 | c.1494T>G p.H498Q | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.454); catalogued as rs1420459911, COSV58013468; called by muse, mutect2, varscan2
- FBXO40 | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV57525498; called by muse, mutect2, varscan2
- FCRLA | c.316C>T p.Q106* (on ENST00000367959; = p.Q83* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 34/36 reads (94%) | catalogued as COSV99376134; called by mutect2, varscan2
- FSHR | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); catalogued as COSV100437308, COSV58623844; called by muse, mutect2, varscan2
- FSHR | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.922); catalogued as COSV100437309; called by mutect2, varscan2
- FZD8 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65968421; called by mutect2, varscan2
- GABRQ | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV64781004; called by muse, mutect2, varscan2
- GALNT15 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs577707435, COSV100327638, COSV60215364; called by muse, mutect2, varscan2
- GALNT17 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.566); catalogued as rs1562745381, COSV61186554; called by muse, varscan2
- GLIPR1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574219796, COSV56990729; called by mutect2, varscan2
- GLYAT | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV53540439; called by muse, varscan2
- GOLGA1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60617187; called by muse, mutect2, varscan2
- GPD1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774262823, COSV99993805; called by muse, mutect2, varscan2
- GPD1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1364920222, COSV99993807; called by mutect2, varscan2
- GRIA1 | c.2521-1G>A p.X841_splice | Splice Site (SNP) | VAF 35/44 reads (80%) | catalogued as COSV53621180; called by muse, mutect2, varscan2
- GRM7 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs267599933, COSV63130808; called by mutect2, varscan2
- GTF2IRD2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV100736432; called by muse, mutect2, varscan2
- GUCA1C | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs866962064, COSV53756001, COSV99659557; called by mutect2, varscan2
- H1-5 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 149/174 reads (86%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs1038798603, COSV58901325; called by muse, mutect2, varscan2
- HEATR9 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs765382917; called by mutect2, varscan2
- HMBOX1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 177/210 reads (84%) | catalogued as COSV55071575; called by muse, mutect2, varscan2
- HRH1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV67955914, COSV67955995; called by muse, mutect2, varscan2
- HUWE1 | c.9817C>T p.H3273Y | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99472632; called by mutect2, varscan2
- IGHV4-39 | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs781431113; called by muse, varscan2
- ITIH1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56258097; called by muse, mutect2, varscan2
- KCNJ8 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53717466; called by muse, mutect2, varscan2
- KCNK5 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.696); catalogued as COSV63988492; called by muse, mutect2, varscan2
- KCNT2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.43); catalogued as COSV54104625, COSV54105199; called by muse, mutect2, varscan2
- KCNV2 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0.249); catalogued as COSV66057373; called by muse, mutect2, varscan2
- KDM6B | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV99641618; called by muse, mutect2, varscan2
- KIF16B | c.3214C>T p.Q1072* | Nonsense Mutation (SNP) | VAF 67/151 reads (44%) | catalogued as COSV61713047; called by muse, mutect2, varscan2
- KIF21B | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59757651; called by mutect2, varscan2
- KIR2DL4 | c.1144C>T p.P382S (on ENST00000396284; = p.P308S on NM_001080770.2) | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.084); catalogued as rs1413239426; called by muse, mutect2, varscan2
- KRT72 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1294547368, COSV53374900; called by muse, mutect2, varscan2
- LARP4B | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.839); catalogued as rs941682595, COSV100295387; called by muse, varscan2
- LNPK | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs147224445; called by muse, mutect2, varscan2
- LPP | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV57111812; called by muse, mutect2, varscan2
- LRP5 | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53722721; called by muse, mutect2, varscan2
- LRRN1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.981); catalogued as COSV60015373; called by muse, mutect2, varscan2
- LTBP2 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56213398; called by muse, mutect2, varscan2
- LTBP4 | c.3743T>C p.L1248P (on ENST00000308370 / NM_001042544.1; = p.L1211P on NM_003573.2) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99193744; called by muse, mutect2, varscan2
- LYN | c.491G>C p.S164T | Missense Mutation (SNP) | VAF 88/107 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV70206338; called by muse, mutect2, varscan2
- LZTR1 | c.614T>G p.I205S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV53151238; called by muse, mutect2, varscan2
- MAGEB10 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs1323890664, COSV63312543; called by mutect2, varscan2
- MAP3K5 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 100/129 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62887045; called by muse, mutect2, varscan2
- MAP7 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100643903; called by mutect2, varscan2
- MAP7 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs267600828, COSV100643904; called by muse, mutect2, varscan2
- MFNG | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as COSV63690784; called by muse, mutect2, varscan2
- MICAL2 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 159/185 reads (86%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as COSV56325551; called by muse, mutect2, varscan2
- MUC16 | c.14315C>T p.P4772L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV67489117; called by muse, varscan2
- MYO15A | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as rs368682932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.2353T>C p.S785P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.358); catalogued as rs1313649846, COSV55735762; called by muse, mutect2, varscan2
- NOL10 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV62042523; called by muse, mutect2, varscan2
- NOVA2 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV54359507; called by muse, mutect2, varscan2
- NOX5 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs768089495, COSV52995032; called by muse, mutect2, varscan2
- NRDE2 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs560359168, COSV62964465; called by muse, mutect2, varscan2
- NRP1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV99588860; called by muse, mutect2, varscan2
- NUP214 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV63912682; called by muse, mutect2, varscan2
- OR10A3 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as COSV100660337, COSV62460109; called by muse, mutect2, varscan2
- OR13F1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs138844331, COSV58251019, COSV58252557; called by muse, mutect2, varscan2
- OR14C36 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 71/77 reads (92%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as rs748761952, COSV58602621; called by muse, mutect2
- OR2A5 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV68739067; called by muse, mutect2, varscan2
- OR4K13 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59860652; called by muse, mutect2, varscan2
- OR52E4 | c.29A>C p.Y10S | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV57625976; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- OR5AR1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57255171; called by muse, mutect2, varscan2
- OR6C65 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.712); catalogued as COSV65569304; called by muse, mutect2, varscan2
- OR6C76 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.178); catalogued as COSV60389903; called by muse, mutect2, varscan2
- OR7D2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV100712959, COSV60141078; called by mutect2, varscan2
- OR7D4 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as rs772121392, COSV58072387; called by muse, mutect2, varscan2
- OR7G3 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV59640950; called by muse, mutect2, varscan2
- PAGE2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV66596212; called by muse, mutect2, varscan2
- PCDH15 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.03); catalogued as COSV64670800; called by muse, mutect2, varscan2
- PCDH8 | c.2999G>A p.R1000K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as rs1307805182; called by muse, mutect2
- PCDHB2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 65/75 reads (87%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV52031000; called by muse, mutect2, varscan2
- PCLO | c.2892G>A p.M964I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs267601599, COSV61656092; called by mutect2, varscan2
- PDGFRA | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV57267599, COSV99957459; called by muse, varscan2
- PDZD9 | c.656C>T p.P219L (on ENST00000424898 / NM_001363519.1; = p.P159L on NM_173806.4) | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV99193335; called by muse, varscan2
- PDZD9 | c.655C>T p.P219S (on ENST00000424898 / NM_001363519.1; = p.P159S on NM_173806.4) | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV99193337; called by muse, varscan2
- PIK3R4 | c.3329C>T p.S1110F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV100768084, COSV63243654; called by muse, mutect2, varscan2
- PLG | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs940368459, COSV51983243; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs575779538, COSV100544259; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755838705, COSV100544261; called by muse, mutect2, varscan2
- PRCC | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV54858248; called by mutect2, varscan2
- PRDM11 | c.1411C>T p.P471S (on ENST00000530656 / NM_001359633.1; = p.P437S on NM_001256695.1) | Missense Mutation (SNP) | VAF 75/87 reads (86%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.172); catalogued as COSV55443011; called by muse, varscan2
- PRSS57 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV51261971; called by muse, mutect2, varscan2
- RAG1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 98/110 reads (89%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55026767, COSV55027754; called by mutect2, varscan2
- RASGRP1 | c.1539G>A p.R513= | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as COSV60367341; called by muse, mutect2, varscan2
- RBM27 | c.903T>G p.D301E | Missense Mutation (SNP) | VAF 176/206 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54593792; called by muse, mutect2, varscan2
- RBP2 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51674659; called by muse, mutect2, varscan2
- RC3H1 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 110/122 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51200652, COSV51213964; called by muse, mutect2, varscan2
- ROBO4 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60627592; called by muse, mutect2, varscan2
- RTL8A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as rs1262551143, COSV66188917; called by muse, varscan2
- RUNDC1 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100865815, COSV64512573; called by muse, mutect2, varscan2
- SCAMP5 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.486); catalogued as COSV62644078; called by muse, mutect2, varscan2
- SCML2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs765570208, COSV52624462, COSV52624512; called by muse, mutect2, varscan2
- SEC22C | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52567053, COSV52567683; called by mutect2, varscan2
- SERPINB11 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs763954981, COSV66957718; called by mutect2, varscan2
- SH2D4B | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV57900836; called by muse, mutect2, varscan2
- SH3RF2 | c.1844C>A p.P615Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV63037074, COSV63041090; called by muse, mutect2, varscan2
- SH3TC1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV55289035; called by muse, mutect2, varscan2
- SIGLEC1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.898); catalogued as rs776149157, COSV52471206; called by muse, mutect2, varscan2
- SLITRK3 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53852722; called by muse, mutect2, varscan2
- SPAG6 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100510335, COSV57623466; called by muse, mutect2, varscan2
- SPHKAP | c.3109C>T p.L1037F | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV60868405, COSV60879780; called by muse, mutect2, varscan2
- SRSF7 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57448228; called by muse, varscan2
- STAB2 | c.5176C>T p.P1726S | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66345780; called by muse, varscan2
- SVOP | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.025); catalogued as rs1253636716, COSV54468453; called by muse, mutect2, varscan2
- SYT2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66143039; called by muse, varscan2
- SYTL5 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV52904950; called by mutect2, varscan2
- TAS2R41 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.152); catalogued as rs763620527, COSV68765797; called by muse, mutect2, varscan2
- TBC1D2B | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV56037931; called by muse, varscan2
- TDRD1 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV52587324, COSV52590970, COSV99314678; called by muse, mutect2, varscan2
- TFDP1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64742447; called by muse, varscan2
- TRAV12-1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.279); catalogued as rs1306698701; called by muse, mutect2, varscan2
- UBAP2 | c.3264+1G>A p.X1088_splice | Splice Site (SNP) | VAF 12/14 reads (86%) | catalogued as COSV54292444; called by muse, mutect2, varscan2
- UBR5 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99641050; called by muse, mutect2, varscan2
- UGT2B4 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 26/31 reads (84%) | catalogued as rs774803544, COSV59317964, COSV59318763; called by mutect2, varscan2
- UNC5C | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs753413609, COSV71661919; called by mutect2, varscan2
- UNC5D | c.933G>A p.W311* | Nonsense Mutation (SNP) | VAF 42/49 reads (86%) | catalogued as COSV54829716; called by muse, mutect2, varscan2
- USH2A | c.11801C>T p.P3934L | Missense Mutation (SNP) | VAF 92/100 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV100232879, COSV56424707; called by muse, mutect2, varscan2
- USP26 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.643); catalogued as COSV63709410; called by muse, mutect2, varscan2
- USP43 | c.2221C>T p.H741Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53306389; called by muse, mutect2
- USP6 | c.2698G>A p.G900R | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51494610; called by muse, mutect2, varscan2
- WDCP | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV54593619; called by muse, mutect2, varscan2
- WEE1 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV55198277; called by muse, varscan2
- WSCD2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs200708985, COSV54589936; called by muse, mutect2, varscan2
- XIRP2 | c.6759A>C p.K2253N (on ENST00000628543; = p.K2428N on NM_152381.6) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV54729864; called by muse, mutect2
- XYLT1 | c.2825G>A p.S942N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54495226; called by muse, mutect2, varscan2
- ZC3H14 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV51773074; called by muse, varscan2
- ZDHHC17 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 135/320 reads (42%) | catalogued as COSV58353920; called by muse, mutect2, varscan2
- ZMAT1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV65659904; called by muse, varscan2
- ZNF107 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV61331468; called by muse, mutect2, varscan2
- ZNF251 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 95/113 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs756744977, COSV52958414; called by muse, mutect2, varscan2
- ZNF33A | c.1736C>T p.P579L (on ENST00000458705 / NM_006974.3; = p.P580L on NM_006954.2) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56727392; called by muse, mutect2, varscan2
- ZNF385D | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV55771708; called by mutect2, varscan2
- ZNF616 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57511499; called by mutect2, varscan2
- KIR3DL3 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYBBP1A | c.1308_1310dup p.S437dup | In Frame Ins (INS) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- ABCA3 | c.4452G>A p.R1484= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV57059091; called by muse, mutect2, varscan2
- ADCY8 | c.3022C>T p.L1008= | Silent (SNP) | VAF 89/105 reads (85%) | catalogued as COSV53924165; called by muse, mutect2, varscan2
- ADCY8 | c.2352C>T p.A784= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as COSV53923611, COSV53926136; called by muse, mutect2, varscan2
- AK2 | c.558C>T p.S186= (on ENST00000354858; = p.S228= on NM_001625.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 93/108 reads (86%) | catalogued as COSV61469852; called by muse, mutect2, varscan2
- ANKS1B | c.1107G>A p.G369= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV61344149; called by muse, mutect2, varscan2
- ANKS6 | c.1776G>A p.Q592= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs565730859, COSV62049849, COSV62051878; called by muse, mutect2, varscan2
- ARHGEF40 | c.1383C>T p.A461= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs917993677, COSV53883810; called by muse, mutect2, varscan2
- ATMIN | c.1056C>T p.I352= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV55147376; called by muse, mutect2, varscan2
- BMX | c.612C>T p.S204= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV59593221; called by muse, mutect2, varscan2
- C16orf92 | c.57A>C p.P19= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99662458; called by muse, mutect2, varscan2
- CAMKV | c.453G>A p.L151= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV56557534; called by muse, mutect2, varscan2
- CARMIL3 | c.816C>T p.S272= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100549635; called by muse, mutect2, varscan2
- CCDC33 | c.51C>T p.I17= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs778105434, COSV58352262; called by mutect2, varscan2
- CHRM2 | c.837G>A p.E279= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV57778534, COSV57782717; called by muse, mutect2, varscan2
- CNTNAP1 | c.1002C>T p.I334= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV52850821; called by mutect2, varscan2
- CORO7 | c.1029C>T p.Y343= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs755640512, COSV52033497; called by muse, mutect2, varscan2
- DOCK10 | c.6480G>A p.V2160= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs368183880; called by muse, mutect2, varscan2
- DPYD | c.3042G>A p.K1014= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as rs1336778564, COSV64612393; called by muse, varscan2
- DSC3 | c.2259C>T p.T753= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV64574549, COSV64575087; called by muse, mutect2, varscan2
- EFTUD2 | c.1242C>T p.P414= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as rs1433562191, COSV68184650; called by muse, mutect2, varscan2
- EXOSC1 | c.402C>T p.S134= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV58356241; called by muse, mutect2, varscan2
- F2 | c.1021C>T p.L341= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV61317461; called by muse, mutect2, varscan2
- FAM114A2 | c.1378C>T p.L460= | Silent (SNP) | VAF 61/65 reads (94%) | catalogued as COSV61078636; called by muse, mutect2, varscan2
- FAM124A | c.114T>A p.V38= (on ENST00000322475 / NM_001242312.2; = p.V74= on NM_145019.4) | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV54479670; called by muse, mutect2
- FASTKD5 | c.264C>T p.A88= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV53909059; called by muse, mutect2, varscan2
- FAT3 | c.4530G>A p.R1510= | Silent (SNP) | VAF 148/177 reads (84%) | catalogued as COSV53164778; called by muse, mutect2, varscan2
- FCRLA | c.315C>T p.L105= (on ENST00000367959; = p.L82= on NM_032738.4) | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as rs1190249930, COSV99376125; called by muse, mutect2, varscan2
- FLT3 | c.1854A>G p.S618= | Silent (SNP) | VAF 134/181 reads (74%) | catalogued as rs140784892; called by muse, mutect2, varscan2
- FRMD5 | c.420C>T p.I140= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV68724995; called by muse, mutect2, varscan2
- GAB4 | c.348G>A p.Q116= | Silent (SNP) | VAF 77/178 reads (43%) | catalogued as COSV68755093; called by muse, mutect2, varscan2
- GNA14 | c.621G>A p.S207= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs371304229; called by muse, mutect2, varscan2
- HLTF | c.2226G>A p.K742= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV59503299; called by muse, mutect2, varscan2
- HSPA2 | c.1038C>T p.I346= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV55971086; called by muse, mutect2, varscan2
- HUWE1 | c.9816A>T p.L3272= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as COSV99472633; called by muse, mutect2, varscan2
- KDM6B | c.1077C>T p.D359= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs770025410, COSV54681714; called by muse, mutect2, varscan2
- KIF16B | c.1938C>T p.I646= | Silent (SNP) | VAF 80/180 reads (44%) | catalogued as rs749576471, COSV61701389, COSV61717207; called by muse, mutect2, varscan2
- LARP4B | c.24G>A p.K8= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100295390; called by muse, varscan2
- LDB3 | c.303G>A p.P101= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs559350698, COSV53948411; called by muse, mutect2, varscan2
- LNPK | c.681C>T p.S227= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs754861937, COSV55826658; called by muse, mutect2, varscan2
- LRMDA | c.72C>T p.F24= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV65277361; called by mutect2, varscan2
- LRRK1 | c.2100C>T p.I700= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs746303850, COSV52614159; called by mutect2, varscan2
- LTBP4 | c.3742C>T p.L1248= (on ENST00000308370 / NM_001042544.1; = p.L1211= on NM_003573.2) | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99193676; called by muse, mutect2
- LYPD1 | c.141G>T p.T47= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV58470816; called by muse, mutect2, varscan2
- LYST | c.3216C>T p.S1072= | Silent (SNP) | VAF 92/98 reads (94%) | catalogued as COSV67712942; called by muse, mutect2, varscan2
- MPEG1 | c.1596T>C p.F532= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV57094488; called by muse, mutect2, varscan2
- MRGPRX1 | c.108C>T p.I36= | Silent (SNP) | VAF 88/188 reads (47%) | catalogued as COSV57107605, COSV57107683; called by mutect2, varscan2
- MUC16 | c.10059G>A p.G3353= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV67489124; called by muse, mutect2, varscan2
- MYO1A | c.3048C>T p.V1016= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs747253822, COSV55657024; called by mutect2, varscan2
- NCAPD3 | c.2554C>T p.L852= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as COSV73258729; called by muse, varscan2
- NLRC3 | c.831G>A p.G277= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs771644734, COSV57095240; called by muse, mutect2, varscan2
- NLRP9 | c.60G>A p.K20= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as COSV60467174; called by muse, mutect2, varscan2
- NOC2L | c.258C>T p.F86= | Silent (SNP) | VAF 71/76 reads (93%) | catalogued as rs921490884, COSV58533339; called by muse, mutect2, varscan2
- NRP1 | c.990G>A p.L330= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99588865; called by mutect2, varscan2
- OR11H1 | c.267C>T p.F89= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1488523509, COSV99421850; called by mutect2, varscan2
- OR11L1 | c.921G>A p.R307= | Silent (SNP) | VAF 64/177 reads (36%) | catalogued as rs267598485, COSV63314877; called by muse, mutect2, varscan2
- OR5AU1 | c.717C>T p.S239= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV58616112; called by muse, mutect2, varscan2
- PCDH8 | c.3000G>A p.R1000= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100131733, COSV58814765; called by muse, mutect2, varscan2
- PDPR | c.1431T>C p.H477= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV55355954; called by muse, mutect2, varscan2
- PLCG2 | c.1566C>T p.P522= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs753080096, COSV63875369; called by muse, mutect2, varscan2
- PLEKHG7 | c.399C>T p.L133= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV67337736; called by muse, mutect2, varscan2
- PRSS38 | c.174G>A p.G58= | Silent (SNP) | VAF 92/101 reads (91%) | catalogued as COSV64540378; called by muse, mutect2, varscan2
- RHOT2 | c.342C>T p.I114= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs745828382, COSV53474637; called by muse, mutect2, varscan2
- RPH3A | c.1356G>A p.R452= (on ENST00000389385 / NM_001143854.2; = p.R448= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV66993440; called by muse, mutect2, varscan2
- RXFP2 | c.75C>T p.I25= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs773894914, COSV53633381; called by mutect2, varscan2
- RYR1 | c.14577C>T p.F4859= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62108767; called by muse, mutect2, varscan2
- SDR16C5 | c.384C>T p.I128= | Silent (SNP) | VAF 72/86 reads (84%) | catalogued as rs377080872; called by mutect2, varscan2
- SELENOP | c.90A>G p.Q30= | Silent (SNP) | VAF 35/39 reads (90%) | catalogued as rs1395254484, COSV72484775; called by muse, mutect2, varscan2
- SEMA4C | c.1179C>T p.F393= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs762825083, COSV59692133; called by mutect2, varscan2
- SERPINA7 | c.1221G>A p.G407= | Silent (SNP) | VAF 62/70 reads (89%) | catalogued as CD013486, COSV59664759; called by muse, mutect2, varscan2
- SIRT1 | c.1242T>C p.F414= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV53020035; called by muse, mutect2, varscan2
- SLC15A2 | c.1869C>T p.V623= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV55200464; called by mutect2, varscan2
- SLC22A13 | c.505C>T p.L169= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV61291981; called by muse, mutect2, varscan2
- SLITRK5 | c.2055C>T p.F685= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as COSV61520908; called by muse, mutect2, varscan2
- STARD3 | c.1167C>T p.I389= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs753831085, COSV59224562; called by muse, mutect2, varscan2
- TBX4 | c.864G>A p.P288= | Silent (SNP) | VAF 66/110 reads (60%) | catalogued as rs1179957328, COSV53607740; ClinVar: likely benign; called by muse, varscan2
- TF | c.1782G>A p.A594= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs778400078, COSV53917621; called by muse, mutect2, varscan2
- TGM7 | c.1731G>A p.T577= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs765625546, COSV71773107; called by muse, varscan2
- TLR4 | c.1122C>T p.S374= (on ENST00000355622 / NM_138554.5; = p.S334= on NM_003266.4) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100842907, COSV62923288, COSV62924132; called by muse, mutect2, varscan2
- TLR7 | c.2184G>A p.L728= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs1312286633, COSV66125383; called by mutect2, varscan2
- TMEM143 | c.552G>A p.Q184= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV53158618; called by muse, mutect2, varscan2
- TMEM39A | c.564C>T p.F188= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs541654492, COSV59901189; called by muse, mutect2, varscan2
- TRAV16 | c.90C>T p.L30= | Silent (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- TRBC2 | c.360C>T p.I120= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs782735204; called by mutect2, varscan2
- UBE3B | c.2532C>T p.G844= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs192120537, COSV61077249; called by muse, mutect2, varscan2
- UBE4B | c.2994C>T p.T998= (on ENST00000343090 / NM_001105562.3; = p.T869= on NM_006048.5) | Silent (SNP) | VAF 80/87 reads (92%) | catalogued as COSV53541090; called by muse, mutect2, varscan2
- VPS13B | c.10590G>A p.R3530= | Silent (SNP) | VAF 106/117 reads (91%) | catalogued as COSV62154898; called by muse, mutect2, varscan2
- WNT10B | c.669C>T p.I223= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56406287; called by muse, varscan2
- XPOT | c.1686C>T p.F562= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV60347745; called by mutect2, varscan2
- ZNF117 | c.996C>T p.P332= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs749884849, COSV51429618; called by muse, mutect2, varscan2
- ZNF142 | c.4197C>T p.P1399= (on ENST00000411696 / NM_001379660.1; = p.P1199= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV101376944; called by muse, mutect2, varscan2
- ZNF335 | c.2154C>T p.S718= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV59817015; called by muse, mutect2, varscan2
- ZNF592 | c.714C>T p.F238= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as rs772393755, COSV55437642; called by muse, mutect2, varscan2
- MIR522 | n.14C>T | RNA (SNP) | VAF 69/168 reads (41%) | called by muse, mutect2, varscan2
- SNORD114-21 | n.2G>A | RNA (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2
- WASF4P | n.1105C>T | RNA (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
